Gene-level copy-number profile of tumor specimen TCGA-OR-A5LF-01A from TCGA case TCGA-OR-A5LF, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 74.4 years (27,179 days).
Specimen TCGA-OR-A5LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.67eb3b89-3122-4d46-8987-ef91c6ba1e0f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a9dee06-7473-4440-9837-ef28e24e7739

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,774; copy number 2: 37,570; copy number 3: 4,937; copy number 4: 15,531.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LF-01A-11D-A309-01): tumor purity 0.72, ploidy 2.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,659,121–39,691,485, 2 genes: NT5C1A, HPCAL4.
- chr1:231,767,464–231,847,706, 2 genes (within-gene range 0–2): AL136171.2, AL136171.1.
- chr3:185,643,130–185,825,042, 3 genes (within-gene range 0–2): IGF2BP2, IGF2BP2-AS1, MIR548AQ.
- chr11:44,656,771–44,656,920, 1 gene: AC104010.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,774. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
